Gene-level copy-number profile of tumor specimen ALCH-AF1N-TTP1-A from ALCHEMIST case ALCH-AF1N, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 47.3 years (17,268 days).
Specimen ALCH-AF1N-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e92accbf-638a-4f86-beda-027e25f854ff.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AF1N-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/cd8bbb25-fee3-4a1f-881e-d72c7d370607

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 512; copy number 1: 1,146; copy number 2: 4,211; copy number 3: 16,212; copy number 4: 19,676; copy number 5: 6,790; copy number 6: 8,516; copy number 7: 1,732; copy number 8: 10; copy number 9: 3; copy number 11: 1; copy number 16: 16; copy number 20: 6; copy number 24: 6; copy number 69: 2; copy number 73: 7; copy number 75: 1; copy number 76: 21; copy number 83: 15; copy number 84: 5; copy number 86: 1; copy number 92: 19; copy number 94: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 104 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:174,724,582–174,850,725, 3 genes, copy number 9 (within-gene range 5–9): MSX2, AC113346.2, MIR4634.
- chr8:127,578,473–128,564,679, 16 genes, copy number 16: AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824.
- chr9:61,642,383–61,642,494, 1 gene, copy number 11: Y_RNA.
- chr12:55,636,860–55,659,795, 4 genes, copy number 73: OR10P1, AC009779.4, OR10AE3P, PSMB3P1.
- chr12:55,757,275–55,827,546, 1 gene, copy number 24 (within-gene range 5–24): AC023055.1.
- chr12:55,818,041–55,900,618, 6 genes, copy number 24–94: ORMDL2, DNAJC14, TMEM198B, MMP19, OLA1P3, GSTP1P1.
- chr12:55,997,180–56,190,284, 19 genes, copy number 92: SUOX, IKZF4, AC034102.8, AC034102.3, RPS26, ERBB3, AC034102.2, PA2G4, AC034102.4, RPL41, ESYT1, ZC3H10, AC034102.7, AC034102.6, AC034102.5, MYL6B, MYL6, SMARCC2, AC073896.4.
- chr12:56,416,363–56,488,414, 5 genes, copy number 84: TIMELESS, MIP, AC097104.1, SPRYD4, GLS2.
- chr12:56,752,161–56,787,790, 1 gene, copy number 75 (within-gene range 3–75): HSD17B6.
- chr12:57,249,609–57,547,224, 16 genes, copy number 83–86 (within-gene range 5–86): AC137834.1, R3HDM2, RNU6-879P, AC126614.1, INHBC, INHBE, AC022506.2, GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2.
- chr12:57,604,622–57,846,729, 27 genes, copy number 20–76: DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2.
- chr12:58,544,124–58,813,060, 2 genes, copy number 69: AC020637.1, LINC02388.
- chr12:58,920,639–59,064,238, 3 genes, copy number 73: AC068305.2, RPS6P22, AC068305.1.

Autosomal genes at a single copy (total copy number 1): 1,146. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
